Somatic mutation profile of tumor specimen MP2PRT-PAUZZP-TMP1-A (aliquot MP2PRT-PAUZZP-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUZZP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,365 days).
Specimen MP2PRT-PAUZZP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a73624af-f4c7-4d10-a19d-b1cc26589c44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUZZP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUZZP-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aee93e66-033b-4d87-a5a8-2c70ec9275d1

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 4, In Frame Ins 2, Nonsense Mutation 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 64/780 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM011725, CM105329; called by muse, mutect2
- BDNF | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.926); catalogued as COSV59237353; called by muse, mutect2, varscan2
- CFAP206 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs749653642; called by muse, mutect2, varscan2
- CXorf66 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as COSV65169610; called by muse, mutect2
- DNAH11 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.473); catalogued as rs775568674; called by muse, mutect2, varscan2
- EP400 | c.3316C>A p.P1106T | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57775880; called by muse, varscan2
- ERC2 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 91/391 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1396505675; called by muse, mutect2, varscan2
- LAMP2 | c.23C>G p.P8R | Missense Mutation (SNP) | VAF 18/549 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs878854484, COSV52352824, COSV52356142; ClinVar: uncertain significance; called by muse, mutect2
- NAALAD2 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428808, COSV58961840; called by muse, mutect2
- TLR4 | c.1264G>C p.E422Q (on ENST00000355622 / NM_138554.5; = p.E382Q on NM_003266.4) | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV62923928; called by muse, mutect2
- UBA2 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55829743; called by muse, mutect2, varscan2
- USP44 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.311); catalogued as rs201091367; called by muse, mutect2, varscan2
- ZSCAN1 | c.964T>A p.C322S | Missense Mutation (SNP) | VAF 123/436 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99991852; called by muse, mutect2, varscan2
- ARHGEF12 | c.3634G>C p.E1212Q | Missense Mutation (SNP) | VAF 55/293 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CRYBG3 | c.5674G>C p.E1892Q | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2
- FMNL2 | c.2288C>G p.S763* | Nonsense Mutation (SNP) | VAF 75/424 reads (18%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.352_353insCCTCCC | In Frame Ins (INS) | VAF 22/92 reads (24%) | called by pindel, varscan2
- LEXM | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NAV3 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2
- PAQR9 | c.942C>G p.F314L | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PHF14 | c.7_8insAGCCCC p.D2_R3insQP | In Frame Ins (INS) | VAF 36/187 reads (19%) | called by mutect2, pindel, varscan2
- RGSL1 | c.3066C>G p.F1022L | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLITRK3 | c.1858G>C p.A620P | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF41 | c.2212C>T p.Q738* | Nonsense Mutation (SNP) | VAF 65/323 reads (20%) | called by muse, mutect2, varscan2
- NPAP1 | c.2808G>T p.L936= | Silent (SNP) | VAF 23/399 reads (6%) | called by muse, mutect2
- OR4D5 | c.675C>G p.L225= | Silent (SNP) | VAF 11/380 reads (3%) | called by muse, mutect2
- RNF148 | c.312C>T p.L104= | Silent (SNP) | VAF 63/396 reads (16%) | called by muse, mutect2, varscan2
- TSR1 | c.663C>T p.L221= | Silent (SNP) | VAF 19/350 reads (5%) | called by muse, mutect2
- DMD | c.8218-773G>A | Intron (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- GNA12 | c.310-19779G>C | Intron (SNP) | VAF 51/239 reads (21%) | called by muse, mutect2, varscan2
